Somatic mutation profile of tumor specimen TCGA-L3-A524-01A (aliquot TCGA-L3-A524-01A-11D-A25L-08) from TCGA case TCGA-L3-A524, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 45.9 years (16,765 days).
Specimen TCGA-L3-A524-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 693e68b7-4eeb-4c9e-b08b-f586d4247b4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L3-A524-10A (Blood Derived Normal), aliquot TCGA-L3-A524-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deabfde6-4579-4585-85dd-05245446e1aa

The open-access MAF lists 369 somatic variants for this specimen: 276 protein-altering or splice-affecting, 83 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 83, Nonsense Mutation 15, Frame Shift Del 11, Splice Site 11, Intron 5, RNA 5, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960000, COSV67960068, COSV67960466; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 32/56 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.4165A>C p.S1389R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99558866; called by muse, mutect2, varscan2
- AC244197.3 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.861); catalogued as COSV100557882; called by muse, mutect2, varscan2
- ACE2 | c.583+1G>C p.X195_splice | Splice Site (SNP) | VAF 141/457 reads (31%) | catalogued as COSV99382616; called by muse, mutect2, varscan2
- ACOT9 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100321228; called by muse, mutect2, varscan2
- ACTC1 | c.130-2A>T p.X44_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99291682; called by muse, mutect2, varscan2
- ADAMTS16 | c.1589T>A p.M530K | Missense Mutation (SNP) | VAF 115/175 reads (66%) | SIFT tolerated (0.97); PolyPhen benign (0.058); catalogued as COSV99940508; called by muse, mutect2, varscan2
- ADAMTS17 | c.631A>T p.T211S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99170425; called by muse, mutect2, varscan2
- ADAMTS20 | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239061; called by muse, mutect2, varscan2
- ADCY10 | c.3053C>A p.S1018Y | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV63241160; called by muse, mutect2, varscan2
- ADGRV1 | c.7744A>C p.I2582L | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV101315632; called by muse, mutect2, varscan2
- AFF3 | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100418228; called by muse, mutect2, varscan2
- AHRR | c.1013A>C p.Q338P | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100326796; called by muse, mutect2
- AMY1B | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 61/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375552; called by muse, mutect2, varscan2
- AMY1B | c.967G>C p.G323R | Missense Mutation (SNP) | VAF 59/405 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375553; called by muse, mutect2, varscan2
- APOB | c.1969G>T p.G657W | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99264413; called by muse, mutect2, varscan2
- ARHGAP6 | c.1630-1G>T p.X544_splice | Splice Site (SNP) | VAF 44/108 reads (41%) | catalogued as COSV100272551; called by muse, mutect2, varscan2
- ARHGEF6 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV99166394; called by muse, mutect2, varscan2
- ASB15 | c.275T>A p.L92H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99306345; called by muse, mutect2, varscan2
- ATG2B | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV100737807; called by muse, mutect2, varscan2
- ATP10A | c.2770G>T p.A924S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs1423592656, COSV100790998; called by muse, mutect2
- AVL9 | c.1297G>C p.A433P | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100594533; called by muse, mutect2, varscan2
- B4GALNT3 | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs142955460, COSV56752611; called by muse, mutect2, varscan2
- BBS4 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV99166400; called by muse, mutect2
- BCORL1 | c.2647G>A p.G883R | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.633); catalogued as rs757026766, COSV99498849; called by muse, mutect2, varscan2
- BMP15 | c.644G>C p.S215T | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99399268; called by muse, mutect2, varscan2
- BMPR2 | c.2167T>C p.F723L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV101001351; called by muse, mutect2, varscan2
- BRIP1 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99369643; called by muse, mutect2, varscan2
- BTBD11 | c.3302G>T p.G1101V (on ENST00000280758 / NM_001018072.2; = p.G638V on NM_001017523.2) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1433791229, COSV99775030; called by muse, mutect2, varscan2
- CA1 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV56279080, COSV99810056; called by muse, mutect2, varscan2
- CACNA1E | c.3612G>A p.K1204= | Splice Region (SNP) | VAF 12/218 reads (6%) | catalogued as COSV100701504; called by muse, mutect2
- CACNA1S | c.3706C>A p.R1236S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100754786; called by muse, mutect2, varscan2
- CAPN6 | c.1166T>G p.F389C | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100136773; called by muse, mutect2, varscan2
- CASR | c.1481G>T p.G494V (on ENST00000490131; = p.G571V on NM_000388.4) | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56140933, COSV99948616; called by muse, mutect2, varscan2
- CD33 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99220151; called by muse, mutect2, varscan2
- CD3G | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV99416528; called by muse, mutect2, varscan2
- CDH19 | c.1545C>A p.N515K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs139196230; called by muse, mutect2, varscan2
- CGNL1 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99847752; called by muse, mutect2, varscan2
- CHP2 | c.19del p.H7Tfs*40 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as COSV55650278; called by mutect2, varscan2
- CNTNAP4 | c.1469C>A p.T490N | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.493); catalogued as rs1219174577, COSV100270034; called by muse, mutect2, varscan2
- CNTNAP5 | c.2376del p.V793Sfs*37 | Frame Shift Del (DEL) | VAF 33/106 reads (31%) | catalogued as COSV70470437; called by mutect2, pindel, varscan2
- COL4A4 | c.930+2T>G p.X310_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100306432; called by muse, mutect2, varscan2
- COL9A2 | c.221A>T p.D74V | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs565528937, COSV101025624; called by muse, mutect2, varscan2
- COLGALT2 | c.173C>A p.A58E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100730444, COSV100730488; called by muse, varscan2
- COPG1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1036322372, COSV100135436; called by muse, mutect2, varscan2
- CPA5 | c.739C>A p.H247N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100812257; called by muse, mutect2, varscan2
- CREB3L3 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV99313961; called by muse, mutect2, varscan2
- CUL4B | c.380T>A p.F127Y | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.101); catalogued as COSV100340258; called by muse, mutect2, varscan2
- CUX2 | c.1697T>A p.L566Q | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99919016; called by muse, mutect2, varscan2
- CXCR3 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV101031565; called by mutect2, varscan2
- CXorf56 | c.382-1G>A p.X128_splice (on ENST00000536133 / NM_001170570.2; = p.X142_splice on NM_022101.4) | Splice Site (SNP) | VAF 38/123 reads (31%) | catalogued as COSV100233356; called by muse, mutect2, varscan2
- DHX8 | c.954G>C p.R318S | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as COSV99292016; called by muse, mutect2, varscan2
- DLK1 | c.300C>A p.N100K | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100375087, COSV57990917; called by muse, mutect2, varscan2
- DMRTA1 | c.994A>T p.I332F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100364701; called by muse, mutect2, varscan2
- DMXL1 | c.7657G>A p.A2553T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs763473560, COSV60722320; called by muse, mutect2, varscan2
- DNAH10 | c.6689C>G p.S2230* (on ENST00000409039; = p.S2169* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV101292101; called by muse, mutect2, varscan2
- DNAH5 | c.2891A>G p.H964R | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99446558; called by muse, mutect2, varscan2
- ECH1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs150942892; called by muse, mutect2, varscan2
- ELMO1 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as COSV100163760, COSV100166617; called by muse, mutect2, varscan2
- EPB41L5 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV55353660, COSV99758425; called by muse, mutect2, varscan2
- ERAS | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868935025, COSV54432482; called by muse, mutect2, varscan2
- ESX1 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV101006412; called by muse, mutect2, varscan2
- EYS | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV100675938; called by muse, mutect2, varscan2
- F8 | c.2185A>G p.S729G | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs1557278860, COSV100811366; called by muse, mutect2, varscan2
- FAM120C | c.2532G>A p.W844* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100069729; called by muse, mutect2, varscan2
- FAM47C | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV100792381; called by muse, mutect2, varscan2
- FAM47C | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100792382; called by muse, mutect2, varscan2
- FANCI | c.387A>T p.L129F | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100167625; called by muse, mutect2, varscan2
- FASN | c.1815G>T p.W605C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100147503; called by muse, mutect2, varscan2
- FAT3 | c.6737T>C p.L2246S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99963363; called by muse, mutect2, varscan2
- FAT4 | c.9436G>T p.G3146C | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100627691, COSV100629603; called by muse, mutect2, varscan2
- FBXO30 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV99395063; called by muse, mutect2, varscan2
- FCN1 | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV100878843; called by muse, mutect2, varscan2
- FHL5 | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); catalogued as COSV100459234; called by muse, mutect2
- FLT3 | c.2239C>A p.P747T | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as COSV99607876; called by muse, mutect2, varscan2
- FMOD | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200924838, COSV61609668; called by muse, mutect2, varscan2
- FOCAD | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV100620172; called by muse, mutect2, varscan2
- FOXK2 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100081968, COSV58878733; called by muse, mutect2, varscan2
- FREM1 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.64); PolyPhen benign (0.055); catalogued as COSV101084008, COSV66532108; called by muse, mutect2, varscan2
- FRMPD1 | c.3008A>T p.E1003V | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as rs1195733769, COSV100899429; called by muse, mutect2, varscan2
- FUNDC2 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV101045422; called by muse, mutect2, varscan2
- GC | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs746003171, COSV99909519; called by muse, mutect2, varscan2
- GNL3L | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100328207; called by muse, mutect2, varscan2
- GPLD1 | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV100015148; called by muse, mutect2, varscan2
- GPM6A | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as COSV99703150; called by muse, mutect2, varscan2
- GPR63 | c.300G>T p.L100F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs374442152, COSV100013203; called by muse, mutect2, varscan2
- GPRASP1 | c.901C>A p.H301N | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100850939; called by muse, mutect2, varscan2
- GREB1 | c.3636G>T p.Q1212H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as rs750700207, COSV99302437; called by muse, mutect2, varscan2
- GRID1 | c.1768A>G p.R590G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs79604666, COSV100022662; called by muse, mutect2, varscan2
- GTPBP4 | c.1011T>A p.D337E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as COSV100672486; called by muse, mutect2, varscan2
- GYG2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100088810; called by muse, mutect2, varscan2
- GYS2 | c.975C>G p.F325L | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV99679561, COSV99680108; called by muse, mutect2, varscan2
- HDAC4 | c.2470C>G p.L824V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV100612911; called by muse, mutect2, varscan2
- HIVEP2 | c.2933G>T p.S978I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99171589; called by muse, mutect2, varscan2
- HLA-A | c.896-2A>T p.X299_splice | Splice Site (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100954328; called by muse, mutect2, varscan2
- HSPA12B | c.42C>T p.I14= | Splice Region (SNP) | VAF 14/180 reads (8%) | catalogued as rs967610282, COSV54765957, COSV54768534; called by muse, mutect2
- IFIH1 | c.3002A>G p.K1001R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99718499; called by muse, mutect2, varscan2
- IGSF1 | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100811949; called by muse, mutect2
- IGSF9B | c.3539G>T p.S1180I | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs767740632, COSV100317209; called by muse, mutect2, varscan2
- IL4R | c.1562G>T p.R521I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99404861; called by muse, mutect2, varscan2
- IMPG1 | c.1274C>A p.A425E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1562365582, COSV64061833; called by muse, mutect2, varscan2
- INSC | c.1106T>C p.M369T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs748632019, COSV101088885, COSV65414034; called by muse, mutect2, varscan2
- INSR | c.3093G>C p.Q1031H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100251739, COSV100253560; called by muse, mutect2, varscan2
- ISX | c.337A>C p.S113R | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100434030; called by muse, mutect2, varscan2
- ITIH2 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100623212; called by muse, mutect2, varscan2
- JMJD1C | c.5492-2A>T p.X1831_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100550281; called by muse, mutect2, varscan2
- KCTD15 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 107/167 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.599); catalogued as rs752211601, COSV99393085, COSV99393423; called by muse, mutect2, varscan2
- KCTD8 | c.1334A>G p.Q445R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100759321; called by muse, mutect2, varscan2
- KDM5A | c.5049G>T p.M1683I | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV101238667; called by muse, mutect2, varscan2
- KLHL10 | c.1195C>A p.R399S | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99509438; called by muse, mutect2, varscan2
- KY | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.753); catalogued as rs150613331; called by muse, mutect2, varscan2
- LAIR1 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100479515; called by muse, mutect2, varscan2
- LAMA2 | c.4222C>A p.R1408S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as COSV101370241, COSV70342405; called by muse, mutect2, varscan2
- LAPTM4B | c.352C>G p.L118V (on ENST00000445593; = p.L27V on NM_018407.6) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV100806186; called by muse, mutect2, varscan2
- LIMA1 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as COSV100372314; called by muse, mutect2, varscan2
- LRP1B | c.13012G>A p.G4338R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs775514879, COSV101254184; called by muse, mutect2, varscan2
- LRP5 | c.3457A>T p.N1153Y | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV99591620; called by muse, mutect2, varscan2
- LRRC66 | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100602875; called by muse, mutect2, varscan2
- LRRK2 | c.6838G>C p.V2280L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100109547, COSV54146884; called by muse, mutect2
- LSAMP | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100369566; called by muse, mutect2, varscan2
- LY6G6C | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as COSV101009687; called by muse, mutect2, varscan2
- MAGEA1 | c.419T>C p.F140S | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100756620; called by muse, mutect2
- MAGEA8 | c.836G>T p.R279M | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54064015, COSV54064794; called by muse, mutect2, varscan2
- MAK | c.1267C>G p.P423A | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV100504324; called by muse, mutect2, varscan2
- MALT1 | c.829-1G>T p.X277_splice | Splice Site (SNP) | VAF 43/81 reads (53%) | catalogued as COSV100618629; called by muse, mutect2, varscan2
- MAOB | c.435C>A p.N145K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100955952; called by muse, mutect2, varscan2
- MAP3K7 | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100997456; called by muse, mutect2, varscan2
- MCAM | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs747992430, COSV50686572, COSV99877619; called by muse, mutect2
- MED26 | c.575T>C p.F192S | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV99659853; called by muse, mutect2, varscan2
- MOG | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV100972975; called by muse, mutect2, varscan2
- MSH6 | c.2896A>G p.T966A | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99315372; called by muse, mutect2, varscan2
- MTMR11 | c.1295C>A p.P432Q (on ENST00000439741 / NM_001145862.2; = p.P360Q on NM_181873.3) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99641008; called by muse, mutect2, varscan2
- MVP | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as COSV62423201; called by muse, mutect2, varscan2
- MYH15 | c.3061G>T p.D1021Y | Missense Mutation (SNP) | VAF 103/405 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV99842641; called by muse, mutect2, varscan2
- MYH7B | c.5803C>A p.Q1935K | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99328022; called by muse, mutect2, varscan2
- NDRG1 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV100105791; called by muse, mutect2, varscan2
- NEB | c.19007G>T p.S6336I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99417414; called by muse, mutect2
- NEUROG1 | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100130743; called by muse, mutect2
- NIPSNAP2 | c.558A>G p.I186M | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs1175689367, COSV100436653; called by muse, mutect2, varscan2
- NLGN2 | c.1684C>G p.P562A | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.44); PolyPhen benign (0.08); catalogued as COSV100080884; called by muse, mutect2, varscan2
- NLRP14 | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100204702; called by muse, mutect2, varscan2
- NPAP1 | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100274960; called by muse, mutect2, varscan2
- NPM1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs774697729, COSV51554335, COSV51569736; called by muse, varscan2
- NRK | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs747386394, COSV99686983; called by muse, mutect2, varscan2
- OR13C2 | c.315G>C p.L105F | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV101604862; called by muse, mutect2, varscan2
- OR13C3 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV101053282; called by muse, mutect2, varscan2
- OR13C5 | c.855G>T p.R285S | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101053043; called by muse, mutect2, varscan2
- OR2M7 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 132/303 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.772); catalogued as COSV100522462; called by muse, mutect2, varscan2
- OR4C3 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs772719961, COSV100167603, COSV60587882; called by muse, mutect2, varscan2
- OR52E6 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551827678, COSV100259201; called by muse, mutect2, varscan2
- OR52E6 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV100259202; called by muse, mutect2, varscan2
- OR5D13 | c.601T>C p.C201R | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs1383130846, COSV100686771; called by muse, mutect2, varscan2
- OR8H1 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV100476917, COSV100476941, COSV57294313; called by muse, mutect2, varscan2
- OTOA | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1268019146, COSV99623976; called by muse, mutect2, varscan2
- OXCT1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.263); catalogued as COSV99541855; called by muse, mutect2, varscan2
- PAH | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 89/148 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199475675, CM056670, COSV100187760, COSV61020569; called by muse, mutect2, varscan2
- PAQR9 | c.701A>T p.D234V | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100503728; called by muse, mutect2, varscan2
- PCDH10 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.953); catalogued as rs766272106, COSV99993198; called by muse, mutect2, varscan2
- PCDH15 | c.5461C>G p.P1821A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100217492; called by muse, mutect2, varscan2
- PCDH15 | c.2713A>T p.M905L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV100217493; called by muse, mutect2
- PCDH15 | c.2711C>A p.T904K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as COSV100217496; called by muse, mutect2
- PCDH17 | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.784); catalogued as COSV100931493; called by muse, mutect2, varscan2
- PCDHAC1 | c.2594G>T p.G865V | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99144298, COSV99145080; called by muse, mutect2, varscan2
- PCDHB10 | c.1030C>G p.P344A | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV53377308, COSV99503917; called by muse, mutect2, varscan2
- PDE3A | c.1271G>C p.R424P | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100761935; called by muse, mutect2, varscan2
- PEG3 | c.235A>T p.T79S | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99687892; called by muse, mutect2, varscan2
- PEX1 | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV99951971; called by muse, mutect2, varscan2
- PFKFB1 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | PolyPhen benign (0.216); catalogued as COSV100895625; called by muse, mutect2
- PIP5K1B | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs148739896; called by muse, mutect2
- PKHD1 | c.2515G>C p.D839H | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV100581854; called by muse, mutect2, varscan2
- PLCL2 | c.2363A>G p.H788R (on ENST00000615277 / NM_001144382.2; = p.H662R on NM_015184.5) | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101196613; called by muse, mutect2, varscan2
- PLPP1 | c.238T>G p.Y80D | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV99301507; called by muse, mutect2, varscan2
- POLG | c.2339A>T p.Q780L | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as COSV99174583; called by muse, mutect2, varscan2
- POU2F1 | c.2160G>T p.Q720H (on ENST00000541643 / NM_001365848.1; = p.Q743H on NM_002697.4) | Missense Mutation (SNP) | VAF 185/391 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV99610669; called by muse, mutect2, varscan2
- PPP1R15A | c.1123G>C p.A375P | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.185); catalogued as rs772671707, COSV99565913; called by muse, mutect2, varscan2
- PPWD1 | c.1786del p.V596* | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as COSV51549819; called by mutect2, pindel, varscan2
- PRPF3 | c.233A>T p.H78L | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV100254620; called by muse, mutect2
- PRPF40B | c.385A>T p.K129* (on ENST00000380281; = p.K123* on NM_012272.3) | Nonsense Mutation (SNP) | VAF 12/21 reads (57%) | catalogued as COSV99979541; called by muse, mutect2, varscan2
- PRPS1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100978846; called by muse, mutect2, varscan2
- PSPH | c.422-1G>A p.X141_splice | Splice Site (SNP) | VAF 18/85 reads (21%) | catalogued as COSV99304136; called by muse, mutect2, varscan2
- PTGDR2 | c.597C>G p.C199W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV99920088; called by mutect2, varscan2
- PTK7 | c.1486G>T p.V496F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100029971; called by muse, mutect2, varscan2
- RAPGEF4 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.579); catalogued as COSV51381243; called by muse, mutect2, varscan2
- RASGRF1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 64/248 reads (26%) | catalogued as COSV101369491, COSV101369530; called by muse, mutect2, varscan2
- RBM5 | c.567+1G>C p.X189_splice | Splice Site (SNP) | VAF 47/113 reads (42%) | catalogued as COSV100762193; called by muse, mutect2, varscan2
- RELT | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV99292744; called by muse, mutect2, varscan2
- RIF1 | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as COSV99690273; called by muse, mutect2, varscan2
- RPAP3 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV99139304; called by muse, mutect2, varscan2
- RYR2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV100768865; called by muse, mutect2, varscan2
- SASH3 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV100795185; called by muse, mutect2, varscan2
- SCN1A | c.5359G>T p.E1787* (on ENST00000303395 / NM_001202435.3; = p.E1776* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 67/181 reads (37%) | catalogued as CM076502, COSV100319701; called by muse, mutect2, varscan2
- SEL1L2 | c.1783G>C p.A595P | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99532840; called by muse, mutect2, varscan2
- SH3BGR | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100374402; called by muse, mutect2, varscan2
- SH3BP5L | c.1042T>G p.C348G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV100821981; called by muse, mutect2, varscan2
- SIPA1L2 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs566304161, COSV53384673; called by muse, mutect2, varscan2
- SLC27A5 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754044176, COSV99564245; called by muse, mutect2, varscan2
- SLC6A19 | c.1145C>G p.T382S | Missense Mutation (SNP) | VAF 153/295 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as COSV100443311; called by muse, mutect2, varscan2
- SLC8A1 | c.1954G>T p.G652* | Nonsense Mutation (SNP) | VAF 44/101 reads (44%) | catalogued as COSV100245182; called by muse, mutect2, varscan2
- SLC8A3 | c.20A>T p.Q7L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as rs1462639397, COSV100776012; called by muse, mutect2, varscan2
- SLC9A4 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99762805; called by muse, mutect2, varscan2
- SPATA4 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 42/68 reads (62%) | catalogued as COSV99708855; called by muse, mutect2, varscan2
- SSU72P8 | c.340C>A p.R114S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs61730745, COSV66361412; called by muse, mutect2, varscan2
- STC2 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV99438203; called by muse, mutect2, varscan2
- SUCNR1 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100751714; called by muse, mutect2, varscan2
- SULF2 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs768084550, COSV63413665; called by muse, mutect2, varscan2
- SYNE1 | c.19861G>C p.E6621Q (on ENST00000367255 / NM_182961.4; = p.E6550Q on NM_033071.3) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.177); catalogued as COSV99556950; called by muse, mutect2, varscan2
- SYNRG | c.1616A>G p.Y539C | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs896489672; called by muse, mutect2, varscan2
- TAF7L | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 52/201 reads (26%) | catalogued as COSV100229390; called by muse, mutect2, varscan2
- TAF7L | c.652T>A p.W218R | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100229392; called by muse, mutect2, varscan2
- TENM1 | c.1979C>A p.P660H | Missense Mutation (SNP) | VAF 133/461 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV100949409; called by muse, mutect2, varscan2
- TET1 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV101017788; called by muse, mutect2, varscan2
- TET2 | c.533A>T p.E178V | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99481719; called by muse, mutect2, varscan2
- THRB | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV99769325; called by muse, mutect2, varscan2
- THSD7B | c.4635G>T p.W1545C (on ENST00000272643; = p.W1543C on NM_001316349.2) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99746569; called by muse, mutect2, varscan2
- TKTL1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99473801; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99143247; called by muse, mutect2, varscan2
- TMEM164 | c.805A>G p.K269E (on ENST00000372068 / NM_032227.4; = p.K120E on NM_017698.2) | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99911478; called by muse, mutect2, varscan2
- TMEM8B | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100941566; called by muse, mutect2, varscan2
- TNRC18 | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs767889251, COSV101269586; called by muse, varscan2
- TNRC6B | c.4622G>T p.G1541V (on ENST00000454349 / NM_001162501.2; = p.G1431V on NM_015088.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100109269; called by muse, mutect2, varscan2
- TRABD2A | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100119715, COSV59104946; called by muse, mutect2, varscan2
- TRAPPC13 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV99198850; called by muse, mutect2, varscan2
- TREH | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99874274; called by muse, mutect2, varscan2
- TRIM25 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 37/218 reads (17%) | catalogued as COSV100380922, COSV57545823; called by muse, mutect2, varscan2
- TRIM68 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV100331651; called by muse, mutect2, varscan2
- TSHZ3 | c.2162C>G p.P721R | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99550444, COSV99550967; called by muse, mutect2, varscan2
- TSPAN6 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100885774; called by muse, mutect2
- TTN | c.84289C>T p.P28097S (on ENST00000591111; = p.P20673S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | PolyPhen probably damaging (0.998); catalogued as COSV100600566; called by muse, mutect2, varscan2
- UBA1 | c.2004-2A>G p.X668_splice | Splice Site (SNP) | VAF 51/170 reads (30%) | catalogued as COSV100255529; called by muse, mutect2, varscan2
- UGT1A1 | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1559415650, CD002728, COSV100529975; called by muse, mutect2, varscan2
- UGT2B7 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV100535134; called by muse, mutect2, varscan2
- UNC93A | c.122C>A p.T41K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100023162; called by muse, mutect2, varscan2
- UTP20 | c.3140G>T p.G1047V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760099420, COSV99881052; called by muse, mutect2, varscan2
- VGLL1 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV101034582; called by muse, mutect2, varscan2
- VNN2 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV100426727, COSV58474003; called by muse, mutect2, varscan2
- VPS51 | c.1357A>T p.I453F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV99659600; called by muse, mutect2, varscan2
- WDR27 | c.309A>T p.E103D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100358395; called by muse, mutect2, varscan2
- WDR45 | c.999C>A p.H333Q (on ENST00000376372 / NM_001029896.2; = p.H334Q on NM_007075.3) | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV100540162, COSV59876576; called by muse, mutect2, varscan2
- XIRP2 | c.5360C>A p.T1787K (on ENST00000628543; = p.T1962K on NM_152381.6) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99740106; called by muse, mutect2, varscan2
- XKR3 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.197); catalogued as COSV100509171; called by muse, mutect2, varscan2
- ZCWPW2 | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 89/150 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV101074629; called by muse, mutect2, varscan2
- ZFHX4 | c.6025C>A p.P2009T | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as COSV99259321; called by muse, mutect2, varscan2
- ZIC1 | c.1115C>A p.T372K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99291658; called by muse, mutect2, varscan2
- ZIC1 | c.1256C>A p.T419K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV99291662; called by muse, mutect2, varscan2
- ZNF350 | c.1384A>T p.T462S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV99702422; called by muse, mutect2, varscan2
- ZNF419 | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99691894; called by muse, mutect2, varscan2
- ZNF526 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1476581122, COSV99725134; called by muse, mutect2, varscan2
- ZNF626 | c.495A>T p.R165S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV101656956; called by muse, mutect2, varscan2
- ZNF662 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as COSV100066120; called by muse, mutect2, varscan2
- ZNF680 | c.1364T>G p.I455S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100549006; called by mutect2, varscan2
- ZNF683 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 53/78 reads (68%) | catalogued as COSV100853675; called by muse, mutect2, varscan2
- ZNF704 | c.458G>C p.S153T | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.275); catalogued as COSV100589393; called by muse, mutect2, varscan2
- ZNF710 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51565664; called by muse, mutect2
- ZNF780A | c.1687G>T p.G563W | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100575004; called by muse, mutect2, varscan2
- ZNF800 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99757772; called by muse, mutect2, varscan2
- ZNF804A | c.2146T>G p.L716V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV100166882; called by muse, mutect2, varscan2
- ZNF804A | c.3247C>T p.P1083S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV100166883; called by muse, mutect2, varscan2
- ZNF808 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1433322798, COSV100707841; called by muse, mutect2, varscan2
- ZNF91 | c.1835T>A p.L612Q | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.151); catalogued as COSV100322369; called by muse, mutect2
- ZP2 | c.1166C>A p.P389Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99559299; called by muse, mutect2, varscan2
- ZRANB3 | c.1915C>A p.P639T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as COSV99922984; called by muse, mutect2, varscan2
- ATM | c.3345del p.Q1116Sfs*10 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | called by mutect2, pindel, varscan2
- CCDC178 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- DPY19L3 | c.2006del p.G669Efs*7 | Frame Shift Del (DEL) | VAF 124/259 reads (48%) | called by mutect2, pindel, varscan2
- FAT1 | c.12367del p.R4123Gfs*83 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel*, varscan2
- FIGN | c.572del p.G191Dfs*110 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- FOXJ2 | c.1153del p.H385Tfs*37 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- FTHL17 | c.358del p.Q120Sfs*34 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | called by mutect2, pindel, varscan2
- IGKV1-5 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 50/195 reads (26%) | called by muse, mutect2, varscan2
- KAT5 | c.746del p.P249Rfs*32 | Frame Shift Del (DEL) | VAF 38/192 reads (20%) | called by mutect2, pindel, varscan2
- PCDHB13 | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.037); called by muse, mutect2
- PCF11 | c.3593del p.S1198Ffs*13 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 28/159 reads (18%) | called by muse, mutect2, varscan2
- TRAV4 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TRBV4-1 | c.102G>C p.M34I | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ADAM30 | c.219C>T p.H73= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs758467993, COSV101023790; called by muse, mutect2, varscan2
- ADCY4 | c.741G>T p.L247= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV99353035; called by muse, mutect2, varscan2
- AKT1S1 | c.489C>T p.G163= (on ENST00000344175 / NM_001098633.4; = p.G183= on NM_032375.5) | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as rs371853543, COSV59274061; called by muse, mutect2, varscan2
- ARL13B | c.477G>T p.L159= (on ENST00000394222 / NM_001174150.2; = p.L52= on NM_144996.4) | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs540645605, COSV100115262; called by muse, mutect2, varscan2
- ASCL3 | c.249C>T p.Y83= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV100366855, COSV57941668; called by muse, mutect2, varscan2
- C11orf87 | c.504G>A p.P168= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1295574975, COSV59357218; called by muse, varscan2
- CACNA1I | c.4770G>T p.L1590= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as COSV100359596; called by muse, mutect2, varscan2
- CCDC141 | c.2673G>T p.R891= | Silent (SNP) | VAF 82/324 reads (25%) | catalogued as rs767273294, COSV99836425; called by muse, mutect2, varscan2
- CIITA | c.1044G>T p.T348= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs140683241, COSV100161567; called by muse, mutect2, varscan2
- CNGB3 | c.501C>A p.P167= | Silent (SNP) | VAF 105/208 reads (50%) | catalogued as COSV100181500; called by muse, mutect2, varscan2
- CNTNAP2 | c.3360C>T p.H1120= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs563414260, COSV62149566; ClinVar: likely benign; called by muse, mutect2, varscan2
- COLEC10 | c.573C>T p.A191= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV100250576, COSV100250887; called by muse, mutect2
- CXorf21 | c.264C>A p.P88= | Silent (SNP) | VAF 49/230 reads (21%) | catalogued as COSV66762461; called by muse, mutect2, varscan2
- DDHD2 | c.1005A>G p.L335= | Silent (SNP) | VAF 66/100 reads (66%) | catalogued as rs770883068, COSV101240551; called by muse, mutect2, varscan2
- DDX17 | c.492T>C p.D164= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99318640; called by muse, mutect2, varscan2
- DGKZ | c.828G>T p.V276= (on ENST00000454345 / NM_001105540.2; = p.V87= on NM_003646.4) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100551190; called by muse, mutect2, varscan2
- DLGAP3 | c.231A>T p.P77= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as COSV99332349; called by muse, mutect2, varscan2
- DMD | c.1542G>A p.V514= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV99920579; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.600G>C p.G200= | Silent (SNP) | VAF 120/154 reads (78%) | catalogued as rs760136204, COSV100668471; called by muse, mutect2, varscan2
- EML4 | c.2130A>G p.K710= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV100580748; called by muse, mutect2, varscan2
- FBLN5 | c.192C>A p.G64= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs770774446, COSV50906868, COSV99969429; called by muse, mutect2, varscan2
- FER | c.534T>A p.L178= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99812053; called by muse, mutect2, varscan2
- FGF8 | c.624C>A p.R208= (on ENST00000344255 / NM_033164.4; = p.R190= on NM_006119.6) | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100199331; called by muse, mutect2, varscan2
- FZD2 | c.723G>A p.T241= | Silent (SNP) | VAF 63/118 reads (53%) | catalogued as rs374854268; called by muse, mutect2, varscan2
- HAO1 | c.411A>T p.R137= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV101113161; called by muse, mutect2, varscan2
- HBD | c.36C>G p.V12= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV53081926, COSV99496608; called by muse, mutect2, varscan2
- ICE1 | c.4986A>T p.P1662= | Silent (SNP) | VAF 220/366 reads (60%) | catalogued as COSV99664106; called by muse, mutect2, varscan2
- IDS | c.18C>A p.T6= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs369954416, COSV100557883, COSV61711411; called by muse, mutect2, varscan2
- IPO8 | c.2433A>C p.G811= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as COSV99804962; called by muse, mutect2, varscan2
- KCNJ12 | c.252G>A p.L84= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs781897017, COSV100054268; called by muse, mutect2, varscan2
- KRT4 | c.1449C>G p.G483= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV99542742; called by muse, mutect2, varscan2
- LRP2 | c.1842G>T p.V614= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV99787121; called by muse, mutect2, varscan2
- MAGEA4 | c.330C>A p.L110= | Silent (SNP) | VAF 57/143 reads (40%) | catalogued as COSV99367372; called by muse, mutect2, varscan2
- MAP3K15 | c.1758G>A p.K586= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs147671630, COSV100134337; called by muse, mutect2, varscan2
- MTMR11 | c.1296G>T p.P432= (on ENST00000439741 / NM_001145862.2; = p.P360= on NM_181873.3) | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV99641007; called by muse, mutect2, varscan2
- MYO18B | c.6921A>G p.A2307= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100122944; called by muse, mutect2, varscan2
- MYOCD | c.444G>C p.T148= | Silent (SNP) | VAF 58/317 reads (18%) | catalogued as COSV100590361; called by muse, mutect2, varscan2
- NEB | c.3819C>A p.T1273= | Silent (SNP) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- NEK11 | c.1056G>T p.A352= | Silent (SNP) | VAF 34/208 reads (16%) | catalogued as COSV100797601; called by muse, mutect2, varscan2
- NLGN4X | c.1866C>A p.P622= | Silent (SNP) | VAF 47/158 reads (30%) | catalogued as COSV52007287, COSV99320518; called by muse, mutect2, varscan2
- NOS1 | c.4197T>C p.I1399= | Silent (SNP) | VAF 14/384 reads (4%) | catalogued as COSV100500227; called by muse, mutect2
- NPAP1 | c.390A>T p.P130= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV100274961, COSV61509511; called by muse, mutect2, varscan2
- NPAP1 | c.1236C>T p.P412= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV100274964; called by muse, mutect2, varscan2
- NTRK3 | c.1893C>T p.A631= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100712448, COSV62298180; called by muse, mutect2, varscan2
- OR2V2 | c.711G>A p.K237= | Silent (SNP) | VAF 39/208 reads (19%) | catalogued as rs1260461369, COSV100080042; called by muse, mutect2, varscan2
- OR4C13 | c.444A>G p.V148= | Silent (SNP) | VAF 47/134 reads (35%) | catalogued as rs147639676, COSV73648928; called by muse, mutect2, varscan2
- OR5AR1 | c.363T>A p.G121= | Silent (SNP) | VAF 48/215 reads (22%) | catalogued as COSV100265602; called by muse, mutect2, varscan2
- OR5D14 | c.525A>T p.V175= | Silent (SNP) | VAF 36/200 reads (18%) | catalogued as COSV100162238; called by muse, mutect2, varscan2
- PAPSS2 | c.1398C>T p.L466= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs749432936, COSV100753458; called by muse, mutect2, varscan2
- PCNX3 | c.5394G>T p.R1798= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100856129; called by muse, mutect2, varscan2
- PID1 | c.513C>A p.A171= (on ENST00000354069 / NM_001330156.1; = p.A169= on NM_017933.5) | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100819578, COSV62478429; called by muse, mutect2, varscan2
- PLSCR2 | c.606A>G p.L202= (on ENST00000497985 / NM_001199978.1; = p.L129= on NM_020359.2) | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100367638; called by muse, mutect2, varscan2
- PRKCZ | c.1431C>T p.I477= | Silent (SNP) | VAF 113/155 reads (73%) | catalogued as rs778602753, COSV66067532; called by muse, mutect2, varscan2
- RBMS1 | c.342A>T p.A114= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100816752; called by muse, mutect2
- RELN | c.399G>T p.V133= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100632870; called by muse, mutect2, varscan2
- RHOB | c.207G>T p.L69= | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as COSV99695175; called by muse, mutect2, varscan2
- SASH3 | c.795C>A p.G265= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV63556259; called by muse, mutect2, varscan2
- SEL1L2 | c.1641T>A p.I547= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV99532843; called by muse, mutect2
- SGIP1 | c.1806T>C p.F602= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV99390870; called by muse, mutect2, varscan2
- SHROOM2 | c.210T>C p.A70= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV101098315; called by muse, mutect2, varscan2
- SMAP1 | c.783A>T p.P261= (on ENST00000370455 / NM_001044305.3; = p.P234= on NM_021940.5) | Silent (SNP) | VAF 42/201 reads (21%) | catalogued as COSV100016731; called by muse, mutect2, varscan2
- SOS2 | c.2625A>T p.A875= | Silent (SNP) | VAF 71/127 reads (56%) | catalogued as rs761442415, COSV99365605; ClinVar: benign; called by muse, mutect2, varscan2
- STAC | c.900G>A p.E300= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs202004976, COSV99829674; called by muse, mutect2, varscan2
- TACC2 | c.180C>G p.T60= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100551839, COSV57745077; called by muse, mutect2, varscan2
- TAS2R10 | c.444G>C p.A148= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV53700673, COSV99555452; called by muse, mutect2, varscan2
- TC2N | c.354C>T p.S118= | Silent (SNP) | VAF 56/120 reads (47%) | catalogued as COSV61747912; called by muse, mutect2, varscan2
- TMEM164 | c.804G>A p.G268= (on ENST00000372068 / NM_032227.4; = p.G119= on NM_017698.2) | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99911477; called by muse, mutect2
- TMEM215 | c.66C>A p.V22= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV100713151; called by muse, mutect2, varscan2
- TOP1MT | c.1389C>T p.A463= | Silent (SNP) | VAF 46/266 reads (17%) | catalogued as COSV100239283; called by muse, mutect2, varscan2
- TPMT | c.144A>G p.L48= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as rs1460997016, COSV100015380; called by muse, mutect2, varscan2
- TPP2 | c.48G>T p.L16= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV101060208; called by muse, mutect2, varscan2
- VPS72 | c.999G>A p.P333= | Silent (SNP) | VAF 97/262 reads (37%) | catalogued as rs199721751; called by muse, mutect2, varscan2
- WDR64 | c.1371A>G p.E457= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100843693; called by muse, mutect2, varscan2
- WDSUB1 | c.630G>A p.Q210= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV100701781; called by muse, mutect2, varscan2
- XIRP2 | c.5361A>G p.T1787= (on ENST00000628543; = p.T1962= on NM_152381.6) | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99740110; called by muse, mutect2, varscan2
- XPO7 | c.1176G>A p.P392= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs762793670, COSV99380936; called by muse, mutect2, varscan2
- ZAN | c.3753T>G p.G1251= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV100769408; called by muse, mutect2, varscan2
- ZC3H12B | c.2085C>A p.A695= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100161579; called by muse, mutect2, varscan2
- ZDHHC14 | c.804C>T p.L268= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100399100; called by muse, mutect2, varscan2
- ZNF529 | c.390C>T p.D130= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs551807727, COSV100485139; called by muse, mutect2, varscan2
- ZNF654 | c.1866T>C p.S622= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100525643; called by muse, mutect2, varscan2
- ZNF711 | c.111T>C p.D37= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV99340777; called by muse, mutect2, varscan2
- ZNF831 | c.3363C>A p.G1121= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as COSV100925880; called by muse, mutect2, varscan2
- ADD1 | c.1413+55T>G | Intron (SNP) | VAF 20/36 reads (56%) | catalogued as COSV99296155; called by muse, mutect2, varscan2
- H2BP2 | n.1062-393G>T | Intron (SNP) | VAF 75/251 reads (30%) | called by muse, mutect2, varscan2
- H2BP2 | n.1062-394G>A | Intron (SNP) | VAF 78/252 reads (31%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-27C>A | Intron (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100025053; called by muse, mutect2, varscan2
- MIR655 | n.56C>A | RNA (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- NXF5 | n.366G>T | RNA (SNP) | VAF 65/253 reads (26%) | catalogued as COSV99534166; called by muse, mutect2, varscan2
- OR3A4P | n.737C>T | RNA (SNP) | VAF 88/118 reads (75%) | catalogued as rs1409423964; called by muse, mutect2, varscan2
- SSPOP | n.4334T>C | RNA (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100022248; called by muse, mutect2, varscan2
- THSD4 | c.-80+14273C>A | Intron (SNP) | VAF 69/125 reads (55%) | catalogued as COSV100802983; called by muse, mutect2, varscan2
- ZNF767P | n.405G>T | RNA (SNP) | VAF 39/271 reads (14%) | called by muse, mutect2, varscan2
